Somatic mutation profile of tumor specimen C3N-02948-01 (aliquot CPT0185620007) from CPTAC case C3N-02948, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G1; Age at diagnosis: 67.9 years (24,802 days).
Specimen C3N-02948-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 41b3bdf3-f303-4ab0-81c2-4e43cfe6ca47.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02948-31 (Blood Derived Normal), aliquot CPT0187250002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cfae543c-f87a-4b3a-b753-c060fb939295

The open-access MAF lists 110 somatic variants for this specimen: 83 protein-altering or splice-affecting, 17 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 66, Silent 17, Nonsense Mutation 8, Frame Shift Del 4, RNA 4, Splice Region 3, Intron 3, Splice Site 2, 3'UTR 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DPYS | c.905G>A p.R302Q | Missense Mutation (SNP) | VAF 28/250 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs200913682, CM102069, COSV60909363; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 25/245 reads (10%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACTR3 | c.1091A>T p.D364V | Missense Mutation (SNP) | VAF 12/116 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.029); catalogued as COSV54303044; called by muse, mutect2, varscan2
- AP3B1 | c.26A>G p.N9S | Missense Mutation (SNP) | VAF 43/390 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs868369063, COSV54893058; called by muse, mutect2, varscan2
- CACNA1E | c.6431C>A p.P2144H (on ENST00000367573 / NM_001205293.3; = p.P2101H on NM_000721.4) | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.942); catalogued as COSV62401324; called by muse, varscan2
- CDH8 | c.2191G>T p.E731* | Nonsense Mutation (SNP) | VAF 20/187 reads (11%) | catalogued as COSV100183310; called by muse, mutect2, varscan2
- DACT3 | c.939C>A p.H313Q | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1406098827; called by muse, mutect2, varscan2
- DNTT | c.498G>C p.Q166H | Missense Mutation (SNP) | VAF 24/176 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV64523328; called by muse, mutect2, varscan2
- ERBB4 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 39/329 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.9); catalogued as rs765191737, COSV53499598; called by muse, mutect2, varscan2
- FAM71B | c.1403G>T p.R468L | Missense Mutation (SNP) | VAF 40/418 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.08); catalogued as COSV57229026; called by muse, mutect2
- FGR | c.743C>T p.T248M | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.683); catalogued as COSV64969582; called by muse, mutect2
- GRIA2 | c.2220C>A p.D740E | Missense Mutation (SNP) | VAF 28/205 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99644123; called by muse, mutect2, varscan2
- KCNJ3 | c.1439G>A p.G480E | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.025); catalogued as COSV54530610; called by muse, mutect2
- KSR2 | c.162del p.E55Kfs*10 | Frame Shift Del (DEL) | VAF 16/204 reads (8%) | catalogued as rs1566104868; called by mutect2, pindel
- LRRIQ3 | c.1127A>G p.H376R | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs1425229044; called by muse, mutect2, varscan2
- MAG | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 24/188 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs1456256662, COSV62698929; ClinVar: uncertain significance; called by muse, varscan2
- MUC16 | c.42821C>A p.P14274H | Missense Mutation (SNP) | VAF 35/253 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs755628119; called by muse, mutect2, varscan2
- NACAD | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV71989434; called by muse, mutect2, varscan2
- NRP2 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 27/268 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as rs764826189, COSV55924199, COSV55927948; called by muse, mutect2, varscan2
- OR2J2 | c.698C>T p.T233I | Missense Mutation (SNP) | VAF 20/151 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.069); catalogued as rs996545889, COSV101013296; called by muse, mutect2, varscan2
- OR52R1 | c.539C>A p.S180* | Nonsense Mutation (SNP) | VAF 23/214 reads (11%) | catalogued as rs763566446; called by muse, mutect2, varscan2
- RYR2 | c.11207C>A p.A3736E | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63679334, COSV63692108; called by muse, mutect2
- SLC24A3 | c.156G>T p.M52I | Missense Mutation (SNP) | VAF 13/134 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as COSV100042966; called by muse, mutect2
- TCOF1 | c.4445A>C p.K1482T (on ENST00000377797 / NM_001135243.1; = p.K1405T on NM_000356.4) | Missense Mutation (SNP) | VAF 44/415 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.082); catalogued as rs1256634783; called by muse, mutect2
- WWP2 | c.739G>T p.E247* | Nonsense Mutation (SNP) | VAF 17/174 reads (10%) | catalogued as COSV100598534; called by muse, mutect2
- ZNF536 | c.2079C>A p.N693K | Missense Mutation (SNP) | VAF 27/234 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs747632104, COSV62817660; called by muse, mutect2, varscan2
- ZNF578 | c.1436G>T p.G479V | Missense Mutation (SNP) | VAF 18/172 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as rs1400105968; called by muse, mutect2, varscan2
- ZNF831 | c.1408G>T p.V470L | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs780396810, COSV64042390; called by muse, mutect2
- ALDH1L1 | c.1765G>C p.A589P | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- ALG3 | c.829C>A p.R277S | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP3B2 | c.1810C>A p.L604M | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.971); called by muse, mutect2
- ARID5A | c.1554G>T p.L518F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); called by muse, varscan2
- BCL2L12 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 35/286 reads (12%) | called by muse, mutect2, varscan2
- BTN1A1 | c.1232C>A p.T411N | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CAPN6 | c.750G>T p.K250N | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CARD10 | c.1315A>G p.S439G | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- CASD1 | c.695A>T p.Y232F | Missense Mutation (SNP) | VAF 21/209 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCER1 | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- CRB1 | c.4006-4C>A | Splice Region (SNP) | VAF 40/457 reads (9%) | called by muse, mutect2
- DLG5 | c.2594G>T p.S865I | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- DNAH17 | c.3364C>T p.L1122F | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNPEP | c.1454A>C p.D485A | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- DYSF | c.1083G>T p.K361N | Missense Mutation (SNP) | VAF 26/361 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); called by muse, mutect2
- EDA2R | c.100G>T p.G34* | Nonsense Mutation (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2
- EEF1G | c.957G>T p.W319C | Missense Mutation (SNP) | VAF 39/347 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- EQTN | c.554G>C p.G185A | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- FGD5 | c.1663G>C p.G555R | Missense Mutation (SNP) | VAF 5/70 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- H2AZ1 | c.374A>G p.Q125R | Missense Mutation (SNP) | VAF 12/119 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- ITGA8 | c.494A>G p.K165R | Missense Mutation (SNP) | VAF 27/249 reads (11%) | SIFT tolerated (1); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- JOSD2 | c.-19G>A | Splice Region (SNP) | VAF 40/173 reads (23%) | called by muse, mutect2, varscan2
- KCNA1 | c.523A>G p.M175V | Missense Mutation (SNP) | VAF 19/141 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP5-3 | c.274T>A p.C92S | Missense Mutation (SNP) | VAF 49/462 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- LIFR | c.3241A>G p.N1081D | Missense Mutation (SNP) | VAF 16/189 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2
- LRP1B | c.7498G>C p.D2500H | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- MAP4K1 | c.1201-1G>C p.X401_splice | Splice Site (SNP) | VAF 20/232 reads (9%) | called by muse, mutect2
- MED12 | c.4639_4646del p.V1547Qfs*28 | Frame Shift Del (DEL) | VAF 13/72 reads (18%) | called by mutect2, pindel
- MNAT1 | c.800G>T p.G267V | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.113); called by muse, mutect2
- MUC16 | c.26612C>A p.T8871K | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MYBL2 | c.1916A>T p.K639M | Missense Mutation (SNP) | VAF 35/302 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- NBAS | c.6843G>T p.V2281= | Splice Region (SNP) | VAF 14/242 reads (6%) | called by muse, mutect2
- NPC1L1 | c.3169T>A p.Y1057N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- OLFM4 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 19/171 reads (11%) | called by muse, mutect2, varscan2
- OOSP1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 24/224 reads (11%) | called by muse, mutect2, varscan2
- PRIMPOL | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- PRPF38B | c.559-2A>T p.X187_splice | Splice Site (SNP) | VAF 9/61 reads (15%) | called by muse, mutect2, varscan2
- PSPH | c.563C>T p.P188L | Missense Mutation (SNP) | VAF 26/294 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.095); called by muse, mutect2
- PTPN22 | c.1417del p.E473Nfs*10 (on ENST00000359785 / NM_001193431.2; = p.E418Nfs*10 on NM_012411.5) | Frame Shift Del (DEL) | VAF 35/315 reads (11%) | called by mutect2, pindel, varscan2
- RASGRF2 | c.1039C>A p.L347M | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- RBM10 | c.2188del p.A730Qfs*72 | Frame Shift Del (DEL) | VAF 20/115 reads (17%) | called by mutect2, pindel, varscan2
- RELN | c.8129A>T p.H2710L | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- RFC1 | c.1639G>A p.D547N | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0); called by muse, mutect2, varscan2
- ROBO1 | c.2823T>A p.F941L | Missense Mutation (SNP) | VAF 19/172 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.459); called by muse, mutect2
- RSL1D1 | c.521A>G p.Y174C | Missense Mutation (SNP) | VAF 23/144 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SEC23B | c.1907C>A p.P636Q | Missense Mutation (SNP) | VAF 37/364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2
- SERPINB2 | c.133G>T p.G45C | Missense Mutation (SNP) | VAF 10/136 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SMOC2 | c.990C>G p.D330E (on ENST00000356284 / NM_001166412.2; = p.D341E on NM_022138.3) | Missense Mutation (SNP) | VAF 17/188 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.739); called by muse, mutect2
- TOMM22 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 17/213 reads (8%) | called by muse, mutect2
- TRANK1 | c.2766G>T p.L922F | Missense Mutation (SNP) | VAF 39/314 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- VPS13B | c.6680C>T p.P2227L | Missense Mutation (SNP) | VAF 33/257 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- XPO5 | c.3335G>A p.R1112K | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.47); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF136 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 25/227 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- ZNF287 | c.1697G>T p.C566F | Missense Mutation (SNP) | VAF 9/66 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF536 | c.861G>T p.E287D | Missense Mutation (SNP) | VAF 33/259 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS12 | c.192G>A p.G64= | Silent (SNP) | VAF 32/223 reads (14%) | catalogued as rs757832544; called by muse, mutect2, varscan2
- ADGRB1 | c.3054G>T p.L1018= | Silent (SNP) | VAF 20/226 reads (9%) | called by muse, mutect2
- BOD1 | c.342T>C p.G114= | Silent (SNP) | VAF 17/130 reads (13%) | called by muse, mutect2, varscan2
- DTX1 | c.1707G>A p.T569= | Silent (SNP) | VAF 20/236 reads (8%) | catalogued as rs374508942, COSV99921622; called by muse, mutect2
- FAT3 | c.579C>T p.F193= | Silent (SNP) | VAF 18/122 reads (15%) | catalogued as COSV53070924; called by muse, mutect2, varscan2
- ISG20L2 | c.615C>T p.N205= | Silent (SNP) | VAF 18/221 reads (8%) | catalogued as rs1244193322; called by muse, mutect2
- ITPKC | c.612C>G p.L204= | Silent (SNP) | VAF 24/227 reads (11%) | called by muse, mutect2, varscan2
- KRTAP13-1 | c.336T>C p.Y112= | Silent (SNP) | VAF 45/423 reads (11%) | catalogued as rs1351605312; called by muse, mutect2, varscan2
- LCE1F | c.210T>G p.S70= | Silent (SNP) | VAF 28/310 reads (9%) | called by muse, mutect2
- NFRKB | c.945A>G p.K315= (on ENST00000446488 / NM_001143835.2; = p.K340= on NM_006165.3) | Silent (SNP) | VAF 25/191 reads (13%) | called by muse, mutect2, varscan2
- OBSCN | c.11826C>T p.C3942= | Silent (SNP) | VAF 63/614 reads (10%) | catalogued as rs746408836; called by muse, mutect2
- PIK3R6 | c.789G>A p.A263= | Silent (SNP) | VAF 39/317 reads (12%) | catalogued as rs1284560058; called by muse, mutect2, varscan2
- PRDM4 | c.1233A>T p.P411= | Silent (SNP) | VAF 19/213 reads (9%) | called by muse, mutect2
- SLC22A4 | c.1008G>C p.R336= | Silent (SNP) | VAF 41/270 reads (15%) | called by muse, mutect2, varscan2
- TMEM82 | c.168G>A p.P56= | Silent (SNP) | VAF 15/107 reads (14%) | catalogued as rs753580713; called by muse, mutect2, varscan2
- XDH | c.2853G>A p.G951= | Silent (SNP) | VAF 44/383 reads (11%) | catalogued as rs746453730, COSV101052425, COSV65147968; called by muse, mutect2, varscan2
- ZNF831 | c.3453C>A p.A1151= | Silent (SNP) | VAF 13/96 reads (14%) | called by muse, mutect2, varscan2
- AC024940.1 | n.4201T>A | RNA (SNP) | VAF 28/280 reads (10%) | called by muse, mutect2
- AGAP7P | n.1697T>A | RNA (SNP) | VAF 65/777 reads (8%) | called by muse, mutect2, varscan2
- ATP8A2P3 | n.455C>G | RNA (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- BIRC8 | n.1216C>T | RNA (SNP) | VAF 26/223 reads (12%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2167G>T | 3'UTR (SNP) | VAF 14/130 reads (11%) | called by muse, mutect2, varscan2
- HTR2C | c.350-24442G>A | Intron (SNP) | VAF 5/88 reads (6%) | catalogued as rs782715436, COSV99351676; called by muse, mutect2
- IL10RA | c.-20G>C | 5'UTR (SNP) | VAF 51/402 reads (13%) | called by muse, mutect2, varscan2
- ITGAX | c.318+42G>A | Intron (SNP) | VAF 14/154 reads (9%) | catalogued as rs1376215287; called by muse, mutect2
- LIM2 | c.175+29C>T | Intron (SNP) | VAF 42/357 reads (12%) | catalogued as rs533314455, COSV99702174; called by muse, mutect2, varscan2
- TRPC4 | c.*1T>C | 3'UTR (SNP) | VAF 7/62 reads (11%) | catalogued as rs1193467061; called by muse, mutect2, varscan2
